Gene-level copy-number profile of tumor specimen TCGA-AX-A1CC-01A from TCGA case TCGA-AX-A1CC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 65.1 years (23,795 days).
Specimen TCGA-AX-A1CC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.5c2f730a-57de-492a-b2bd-3fafa2d68bf2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1CC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b859cfc-e6cc-4b25-8bda-92592ddaf60b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 54,390; copy number 3: 5,085; copy number 4: 164; copy number 5: 150; copy number 8: 1; copy number 9: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A1CC-01A-11D-A134-01): tumor purity 0.29, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 180 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:10,798,397–11,336,675, 1 gene, copy number 9 (within-gene range 2–9): CELF2.
- chr10:11,030,334–18,940,953, 134 genes, copy number 5–9 (broad region; genes not listed).
- chr10:19,051,455–19,052,170, 1 gene, copy number 5: UBE2V2P1.
- chr17:6,057,807–6,124,427, 1 gene, copy number 8: WSCD1.
- chr17:7,217,125–7,514,616, 43 genes, copy number 5: ACADVL, MIR324, DVL2, PHF23, GABARAP, AC120057.2, AC120057.3, CTDNEP1, AC003688.1, ELP5, CLDN7, Y_RNA, SLC2A4, AC003688.2, YBX2, EIF5A, GPS2, AC026954.2, NEURL4, AC026954.1, ACAP1, KCTD11, AC026954.3, TMEM95, TNK1, PLSCR3, TMEM256-PLSCR3, TMEM256, NLGN2, AC113189.2, SPEM1, SPEM2, SPEM3, AC113189.12, TMEM102, AC113189.1, FGF11, AC113189.3, AC113189.4, CHRNB1, ZBTB4, SLC35G6, POLR2A.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
